Gene-level copy-number profile of specimen HCM-BROD-0106-C71-85A from HCMI case HCM-BROD-0106-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,261 days).
Specimen HCM-BROD-0106-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 647c705c-835f-44fe-8eba-6d987948a255.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0106-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/2cf63fe3-958a-4124-93f1-689fd0249d86

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 103; copy number 1: 10,378; copy number 2: 43,798; copy number 3: 4,295; copy number 4: 313; copy number 5: 1; copy number 6: 3; copy number 66: 1; copy number 74: 1; copy number 84: 6; copy number 86: 4; copy number 99: 2; copy number 125: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,349,835–21,559,900, 15 genes: IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39.
- chr9:22,646,200–23,438,700, 4 genes: LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:23,632,106–23,632,360, 1 gene: SUMO2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,249,539–109,307,011, 3 genes, copy number 6: CELSR2, PSRC1, MYBPHL.
- chr1:161,258,745–161,285,450, 1 gene, copy number 5: PCP4L1.
- chr7:54,419,444–55,344,958, 15 genes, copy number 66–125: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.

Autosomal genes at a single copy (total copy number 1): 7,609. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
